CPTAC case C3N-05039 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/82c51ffa-1a1d-466c-ba2f-3351e67fb285

Demographics
Sex at birth: male; Race: asian; Year of birth: 1944; Vital status: Dead; Days to death: 312 days; Year of death: 2019; Country of birth: China.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Temporal lobe; Age at diagnosis: 74.0 years (27,030 days); Year of diagnosis: 2018; Last known disease status: Tumor free; Days to last known disease status: 312 days; Progression or recurrence: no; Days to last follow up: 284 days.
   Pathology details: Greatest tumor dimension: 4 cm.

Follow-up (2 entries)
- Days to follow up: 284 days; Disease response: Tumor Free; Karnofsky performance status: 80; ECOG performance status: 2.
- Days to follow up: 284 days; Disease response: Complete Response; Karnofsky performance status: 80; ECOG performance status: 2.

Other clinical attributes
- Weight: 84 kg; Height: 175 cm; BMI: 27.43.

Exposures
- Tobacco smoking status: Current Smoker; Cigarettes per day: 15; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-05039-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 25 days; Initial weight: 74 mg; Time between excision and freezing: 9 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-05039-21: Section location: Temporal Lobe; Percent tumor nuclei: 75; Percent necrosis: 10.
- Sample C3N-05039-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 25 days; Initial weight: 97 mg; Time between excision and freezing: 9 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-05039-22: Section location: Temporal Lobe; Percent tumor nuclei: 80; Percent necrosis: 10.
- Sample C3N-05039-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 25 days; Method of sample procurement: Blood Draw.
